MMRF case MMRF_1725 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d6173c30-0467-458b-833c-b932ebbd5b21

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.0 years (25,190 days); ISS stage: II; Days to last known disease status: 1,156 days (3.2 years); Days to last follow up: 1,156 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 56 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 57 days; Days to treatment end: 112 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 148 days; Days to treatment end: 196 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 194 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 195 days; Days to treatment end: 195 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 197 days; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 271 days; Days to treatment end: 452 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 452 days (1.2 years); Days to treatment end: 504 days (1.4 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 513 days (1.4 years); Days to treatment end: 627 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 638 days (1.7 years); Days to treatment end: 932 days (2.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 932 days (2.6 years); Days to treatment end: 1,107 days (3.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,107 days (3.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -13 (ECOG 0): M Protein 6.98 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 95.8 mg/dL; Immunoglobulin G 82 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.5 µg/mL; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 104 µmol/L; Calcium 2.26 mmol/L; Albumin 33 g/L; Total Protein 12.9 g/dL; Glucose 5.6 mmol/L.
- Day 85 (ECOG 0): M Protein 1.18 g/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 96 µmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.1 mmol/L.
- Day 176 (ECOG 1): M Protein 6.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.94 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 96 µmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 4.6 mmol/L.
- Day 253 (ECOG 1): M Protein 3.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.48 mg/dL; Immunoglobulin G 8 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 75 µmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.2 g/dL; Glucose 5.7 mmol/L.
- Day 372 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.17 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 75 ×10⁹/L; Creatinine 80 µmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.5 mmol/L.
- Day 428 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.35 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 86 µmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.8 mmol/L.
- Day 540 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.17 mg/dL; Immunoglobulin G 9.8 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.38 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 97 µmol/L; Calcium 2.34 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.8 mmol/L.
- Day 624 (ECOG 1): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.67 mg/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 58 ×10⁹/L; Creatinine 97 µmol/L; Calcium 2.21 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 6.3 mmol/L.
- Day 708 (ECOG 0): M Protein 1.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.25 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 101 µmol/L; Calcium 2.26 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 5.2 mmol/L.
- Day 792 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.24 mg/dL; Immunoglobulin G 9.9 g/L; Immunoglobulin A 1.15 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 88 µmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 4.5 mmol/L.
- Day 876 (ECOG 0): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.87 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 83 µmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.3 g/dL; Glucose 5.1 mmol/L.
- Day 988 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.1 mg/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 1.45 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 88 µmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 5.1 mmol/L.
- Day 1,072 (ECOG 1): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 77 µmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5 mmol/L.
- Day 1,156 (ECOG 0): M Protein 1.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.14 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.57 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 89 µmol/L; Calcium 2.27 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 3.5 mmol/L.

Other clinical attributes
- Day -13: Weight: 75 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1725_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -13 days.
- Sample MMRF_1725_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -13 days.
